Gene-level copy-number profile of tumor specimen TCGA-18-3412-01A from TCGA case TCGA-18-3412, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.1 years (19,025 days).
Specimen TCGA-18-3412-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0d09c6e4-ecdb-493c-849c-58f2a9f2f6d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3412-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e47de000-2c93-4be5-830f-9cc743b03971

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 466; copy number 2: 1,132; copy number 3: 5,717; copy number 4: 20,530; copy number 5: 4,503; copy number 6: 17,234; copy number 7: 3,247; copy number 8: 4,329; copy number 9: 268; copy number 10: 379; copy number 11: 102; copy number 12: 125; copy number 13: 100; copy number 14: 36; copy number 15: 765; copy number 16: 746; copy number 17: 67; copy number 18: 1; copy number 19: 10; copy number 23: 5; copy number 24: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3412-01A-01D-0978-01): tumor purity 0.78, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,129 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:76,185,020–80,648,861, 43 genes, copy number 12–24: AC073091.1, AC073091.2, PNPP1, USP21P2, RN7SKP203, RN7SKP164, AC068616.2, AC068616.3, AC068616.1, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1, AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1.
- chr3:148,192,872–198,222,513, 899 genes, copy number 12–16 (within-gene range 6–16) (broad region; genes not listed).
- chr4:46,918,900–57,207,459, 171 genes, copy number 10–14 (within-gene range 4–14) (broad region; genes not listed).
- chr5:16,373,361–45,696,498, 425 genes, copy number 9–10 (broad region; genes not listed).
- chr11:69,294,151–75,096,964, 206 genes, copy number 10–24 (broad region; genes not listed).
- chr13:62,539,351–62,796,714, 2 genes, copy number 9: AL445668.1, LINC00448.
- chr14:36,533,506–41,604,988, 60 genes, copy number 11–16: PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1, AL049828.2, AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1.
- chr17:45,999,250–47,996,196, 68 genes, copy number 10 (broad region; genes not listed).
- chr18:31,318,160–32,470,882, 40 genes, copy number 13: DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.
- chr19:28,883,430–28,970,874, 1 gene, copy number 12 (within-gene range 4–12): LINC00906.
- chr19:28,949,437–29,564,479, 16 genes, copy number 12: AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B.
- chr19:34,172,504–36,173,853, 138 genes, copy number 11–15 (within-gene range 4–15) (broad region; genes not listed).
- chr19:37,181,579–38,636,955, 60 genes, copy number 13: ZNF585B, ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K.

Autosomal genes at a single copy (total copy number 1): 466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
